Surgical pathology report (de-identified scan), TCGA case TCGA-29-2427, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-2427-01A (Primary Tumor).

[page 1 of 2]
Surg Path

CLINICAL HISTORY:

Malignant neoplasm ovary.

GROSS EXAMINATION:

A. "Omental biopsy (A1)", received fresh for frozen section. Received is a 4 x 3 x 2.1 cm portion of firm tan-white soft tissue. The specimen is serially sectioned and representative section is submitted in block A1.

BLOCK SUMMARY:

A1- representative section of omental biopsy previously submitted as A1
A2-3 representative section of omental biopsy

B. "Omentum", received fresh. Received is a 14 x 7 x 1.7 cm firm, tan-white soft tissue with adherent fat. The specimen is serially sectioned and representative sections are submitted.

B1-5 representative section of omentum

INTRA OPERATIVE CONSULTATION:

A. "Omental biopsy": A1-poorly differentiated carcinoma. Ovarian transitional cell is a possibility. GI tract and pancreas unlikely

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

IMMUNOHISTOCHEMICAL FINDINGS:

Immunoperoxidase stains are obtained on a paraffin block (B1) and show the following results in the tumor cells:

Cytokeratin 7: positive.

Cytokeratin 20: trace positive, focal

CA-125: positive.

Carcinoembryonic antigen: positive.

Wilms Tumor-1 antigen (WT-1): positive (nuclear pattern)

DIAGNOSIS:

A. "OMENTUM" (BIOPSY):

POORLY DIFFERENTIATED ADENOCARCINOMA, MOST CONSISTENT WITH SEROUS ADENOCARCINOMA, SEE COMMENT.

B. "OMENTUM" (OMENECTOMY):

POORLY DIFFERENTIATED ADENOCARCINOMA, MOST CONSISTENT WITH SEROUS ADENOCARCINOMA, SEE COMMENT.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

COMMENT:

[page 2 of 2]
The omentum contains a poorly differentiated adenocarcinoma with no definite areas of papillary architecture. There are only a few areas which show even an equivocal gland formation. Rare psammoma bodies are seen. Although by H&E morphology the appearance is non-specific, the immunohistochemical findings strongly favor a serous carcinoma.

Source: NCI Genomic Data Commons file 0f298857-3531-4e05-9a08-65f5f87b67cc (TCGA-29-2427.B53536CA-770C-4482-B2F7-4284D804DB2E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).